Surgical pathology report (de-identified scan), TCGA case TCGA-14-1827, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1827-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
Hospital #: [REDACTED]
Clinic #: [REDACTED]
DOB/Age/Sex: [REDACTED]
Department: Neurosurgery
Physician: [REDACTED]

Specimen #: [REDACTED]
[REDACTED]
Date of Procedure: [REDACTED]
Date of Receipt: [REDACTED]
Date of Report: [REDACTED]

TISSUE SOURCE:

Part 1: Right occipital brain lesion, [REDACTED]
Part 2: Right occipital brain lesion. [REDACTED]

TCGA-14-1827

CLINICAL DIAGNOSIS & HISTORY:

Name of operation: Craniotomy.
Pre-Operative Diagnosis:
Brain tumor.
Post-Operative Diagnosis:
Same.

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT OCCIPITAL BRAIN LESION (FROZEN SECTION AND TOUCH PREP): INTERMEDIATE GRADE GLIAL NEOPLASM.

The pathologist has reviewed and interpreted the case with the fellow/resident.

[REDACTED]

GROSS DESCRIPTION:

Received are two specimens. Each is labeled with the patient's name and hospital number.

Specimen #1 is received fresh for intraoperative consultation labeled "right occipital brain lesion". The specimen consists of multiple, red-brown, hemorrhagic fragments of tissue measuring in aggregate 1 x 1 x 0.3 cm. The remainder of the cryoblock is submitted in a single cassette labeled "FS1A".

Specimen #2 is received in formalin labeled "right occipital brain lesion". The specimen consists of multiple, soft, brown-tan fragments of tissue measuring in aggregate 1.5 x 1.5 x 0.5 cm. The specimen is submitted in its entirety in a single cassette labeled "2A".

[REDACTED]

[page 2 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
Hospital #: [REDACTED]
Clinic #: [REDACTED]

Specimen #: [REDACTED]
Date of Report [REDACTED]

[REDACTED] TCGA-14-1827 [REDACTED]

MICROSCOPIC DESCRIPTION:

Section one shows cells with astrocytic features with moderate atypia. No neovascularization or necrosis is noted. Although mitoses are not conspicuous, MIB-1 stain is approximately 25% positive.

Section two shows astroglial lesion with marked atypia, numerous mitoses, vascular changes and marked necrosis.

DIAGNOSIS

BRAIN, RIGHT OCCIPITAL (BIOPSY, FS): GLIOBLASTOMA MULTIFORME.

BRAIN, RIGHT OCCIPITAL (BIOPSY): GLIOBLASTOMA MULTIFORME.

[REDACTED]

Tissue Committee Code: 1

Source: NCI Genomic Data Commons file 4962aaaf-6857-40e4-b89a-652b37407ba4 (TCGA-14-1827.D2455471-6972-448D-867B-BDFF3CE64049.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).